Somatic mutation profile of tumor specimen TARGET-20-PATLHB-04A (aliquot TARGET-20-PATLHB-04A-01D) from TARGET case TARGET-20-PATLHB, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.7 years (4,632 days).
Specimen TARGET-20-PATLHB-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29d49146-23aa-403b-8dd6-ffbf052c3e8d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATLHB-14A (Bone Marrow Normal), aliquot TARGET-20-PATLHB-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d26567bb-d631-4981-b22a-6d3634f4ba15

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: In Frame Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.1252_1256delinsGG p.Y418_D419delinsG | In Frame Del (DEL) | VAF 45/152 reads (30%) | catalogued as COSV55393956; called by pindel, varscan2*
- HOXA5 | c.327G>A p.S109= | Silent (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
